Somatic mutation profile of tumor specimen 0DPBGU from CCDI case PBCDDR, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Ependymoma, NOS; Tissue or organ of origin: Ventricle, NOS; Age at diagnosis: 4.3 years (1,581 days).
Specimen 0DPBGU: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) eca08662-69de-4ad9-886a-ccb645b90d81.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DPBFC (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/86b46194-7bb9-4ba2-9cdc-334b2eebcde7

The open-access MAF lists 7 somatic variants for this specimen: 6 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 5, Splice Site 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CSPG4 | c.1838C>T p.A613V | Missense Mutation (SNP) | VAF 329/779 reads (42%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as rs773812855; called by muse, varscan2
- KLC1 | c.335G>A p.R112H | Missense Mutation (SNP) | VAF 582/1476 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs968582543, COSV55809263; called by muse, varscan2
- LTBP2 | c.2330C>T p.T777M | Missense Mutation (SNP) | VAF 527/1264 reads (42%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.65); catalogued as COSV99999517; called by muse, varscan2
- FURIN | c.509G>A p.G170E | Missense Mutation (SNP) | VAF 349/866 reads (40%) | SIFT tolerated (0.63); PolyPhen benign (0.01); called by muse, varscan2
- LAMB4 | c.1361-1G>A p.X454_splice | Splice Site (SNP) | VAF 247/465 reads (53%) | called by muse, varscan2
- PRKDC | c.11885G>A p.R3962Q | Missense Mutation (SNP) | VAF 510/1180 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- LPCAT2 | c.75G>A p.R25= | Silent (SNP) | VAF 430/902 reads (48%) | called by muse, varscan2
